Somatic mutation profile of tumor specimen TCGA-CV-7438-01A (aliquot TCGA-CV-7438-01A-21D-2129-08) from TCGA case TCGA-CV-7438, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 87.7 years (32,021 days).
Specimen TCGA-CV-7438-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b09af37-05b2-4984-9932-ce5dece3e97c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7438-10A (Blood Derived Normal), aliquot TCGA-CV-7438-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/433853d0-556a-4ae0-991f-eac0907b5421

The open-access MAF lists 109 somatic variants for this specimen: 85 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 22, Nonsense Mutation 6, Frame Shift Del 4, Intron 1, RNA 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1810T>C p.C604R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV55888333; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 28/54 reads (52%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC008763.3 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs1461187623, COSV100365374; called by muse, mutect2, varscan2
- ACSS1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV100053756, COSV100054137; called by mutect2, varscan2
- ADAMTS14 | c.2598G>T p.G866= | Splice Region (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100941601; called by muse, mutect2, varscan2
- ANO1 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs776853021, COSV100304059; called by muse, mutect2, varscan2
- ART1 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV99167174; called by muse, mutect2, varscan2
- BLNK | c.1103C>G p.S368* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99813923; called by muse, mutect2, varscan2
- CABIN1 | c.3058G>C p.E1020Q | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV99573277; called by muse, mutect2, varscan2
- CDH10 | c.1950C>G p.I650M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.973); catalogued as COSV100051591; called by muse, mutect2, varscan2
- CDH10 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 6/166 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100050450; called by muse, mutect2
- CFHR4 | c.139G>T p.A47S (on ENST00000367416 / NM_001201551.2; = p.A48S on NM_006684.5) | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.105); catalogued as COSV99260519; called by muse, mutect2, varscan2
- CLCA4 | c.905T>C p.I302T | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.086); catalogued as COSV99760514; called by muse, mutect2, varscan2
- COL9A2 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760341544, COSV101025706; called by muse, mutect2
- CYP1A2 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV100673865; called by muse, mutect2, varscan2
- DLL1 | c.821G>A p.C274Y | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100816077; called by muse, mutect2, varscan2
- DMD | c.5285A>G p.H1762R | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100819807; called by muse, mutect2, varscan2
- DVL3 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs1297965006, COSV100493665; called by muse, mutect2
- EPHA6 | c.2155G>C p.E719Q (on ENST00000389672 / NM_001080448.3; = p.E111Q on NM_173655.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101062926; called by muse, mutect2, varscan2
- EPO | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs781324278, COSV53160987; called by muse, mutect2, varscan2
- ESPL1 | c.3614C>T p.S1205F | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.282); catalogued as COSV99229356; called by muse, mutect2, varscan2
- FKBP4 | c.1016T>C p.I339T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.412); catalogued as rs539277079, COSV99133746; called by muse, mutect2, varscan2
- FN1 | c.2062G>A p.G688S | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375296345, COSV60554062; called by muse, mutect2, varscan2
- GNAL | c.889G>C p.D297H (on ENST00000269162 / NM_001142339.3; = p.D374H on NM_182978.4) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV99303594; called by muse, mutect2, varscan2
- HGH1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs1169644734; called by muse, mutect2
- HPR | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768382715, COSV99930911; called by muse, mutect2, varscan2
- IFT122 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as COSV56208072; called by muse, mutect2, varscan2
- IGF2R | c.1055A>G p.Y352C | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs751282169, COSV100807420; called by muse, mutect2, varscan2
- INSL4 | c.313A>C p.K105Q | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.439); catalogued as COSV99497141; called by muse, mutect2
- JAG1 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs758876727, COSV99652945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JAKMIP3 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV100059219; called by muse, mutect2, varscan2
- KCNG4 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs772060710, COSV57583408; called by muse, mutect2, varscan2
- KIF18A | c.1599G>T p.K533N | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99588723; called by muse, mutect2, varscan2
- KRT14 | c.797G>C p.G266A | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99390894, COSV99391035; called by muse, mutect2
- LAMA4 | c.4636G>A p.E1546K (on ENST00000230538 / NM_001105206.3; = p.E1539K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1456861210, COSV57895144; called by muse, mutect2, varscan2
- LRIG3 | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | catalogued as COSV100292647; called by muse, mutect2
- LRP1 | c.4361+1G>T p.X1454_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99675936; called by muse, varscan2
- MUC5AC | c.13888C>G p.L4630V | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.14); catalogued as COSV100611462; called by muse, mutect2, varscan2
- MYH3 | c.3246G>C p.K1082N | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56868225, COSV56871540; called by muse, mutect2, varscan2
- NBPF15 | c.1886G>A p.R629K | Missense Mutation (SNP) | VAF 26/609 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.114); catalogued as rs782505072; called by muse, mutect2
- NEB | c.2879G>C p.G960A | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99423559; called by muse, mutect2
- NUP205 | c.5387G>A p.R1796Q | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs759831224, COSV99607041, COSV99607525; called by muse, mutect2, varscan2
- OR8U1 | c.901C>G p.L301V | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV100163914; called by muse, varscan2
- PCDHB14 | c.2306C>A p.P769Q | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99505955; called by muse, mutect2
- PDE3A | c.2749G>A p.V917I | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs148455779; called by muse, mutect2, varscan2
- PDXDC1 | c.783G>C p.E261D | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV100363195; called by muse, mutect2, varscan2
- PODXL2 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100686412; called by muse, mutect2, varscan2
- PPFIA2 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780567907, COSV100333550; called by muse, mutect2, varscan2
- PTGFR | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs771837091, COSV100882296; called by muse, mutect2
- RELN | c.9430A>G p.T3144A | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV100633822; called by muse, mutect2, varscan2
- RRP1 | c.321G>T p.W107C | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101513872; called by muse, mutect2
- RXFP2 | c.400A>C p.M134L | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100034345; called by muse, mutect2
- SCYL1 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99534134; called by muse, mutect2, varscan2
- SDK1 | c.3179C>T p.T1060I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs367596251; called by muse, mutect2, varscan2
- SETD2 | c.6807T>G p.N2269K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV100339031; called by muse, mutect2, varscan2
- SFMBT1 | c.2197G>C p.E733Q | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.469); catalogued as COSV99966125; called by muse, mutect2
- SIN3B | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99931750; called by muse, mutect2, varscan2
- SLC39A7 | c.592C>G p.H198D | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as COSV100807699; called by muse, mutect2, varscan2
- SLC9A6 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV100857902; called by muse, mutect2, varscan2
- SLIT3 | c.3431G>A p.R1144H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs200999102, COSV100267669; called by muse, mutect2, varscan2
- SOBP | c.518T>G p.F173C | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100433168; called by muse, mutect2
- SPOP | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.473); catalogued as COSV100753397; called by muse, mutect2, varscan2
- SPSB2 | c.497_498del p.R166Tfs*125 | Frame Shift Del (DEL) | VAF 27/109 reads (25%) | catalogued as rs1221579540; called by pindel, varscan2
- TAS2R40 | c.812T>C p.F271S | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV101282998; called by muse, mutect2, varscan2
- TGM4 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs201751613, COSV56093135; called by muse, mutect2, varscan2
- TPD52 | c.551T>A p.L184* (on ENST00000379097 / NM_001025252.3; = p.L144* on NM_005079.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as COSV100990811; called by muse, mutect2, varscan2
- TRPM7 | c.4895C>T p.T1632I | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100539884; called by muse, mutect2, varscan2
- TWF2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1353478332, COSV100564531; called by muse, mutect2
- UBR5 | c.487A>T p.T163S | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.899); catalogued as COSV99640941; called by muse, mutect2, varscan2
- UNC93A | c.1291G>A p.V431M | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs536332358, COSV57808510; called by muse, mutect2
- USH2A | c.10699C>A p.L3567M | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100235270; called by muse, mutect2, varscan2
- USP4 | c.521A>C p.N174T | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs567871548, COSV99649365; called by muse, mutect2, varscan2
- VIT | c.1091C>T p.T364I (on ENST00000389975 / NM_001177969.1; = p.T379I on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.16); catalogued as COSV101007116; called by muse, mutect2
- WFDC8 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.704); catalogued as rs565130625, COSV99250472; called by muse, mutect2, varscan2
- WNK1 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs759393178, COSV100267487; called by muse, mutect2, varscan2
- XPO4 | c.1903G>T p.G635C | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV99688639; called by muse, mutect2, varscan2
- ZFP36L1 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.677); catalogued as COSV100322703; called by muse, mutect2, varscan2
- ZNF208 | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.951); catalogued as COSV101237027; called by muse, mutect2, varscan2
- ZNF449 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as COSV100202978; called by muse, mutect2
- ZNF718 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as COSV101210258; called by muse, mutect2, varscan2
- ZXDA | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.419); catalogued as COSV100699425; called by muse, mutect2
- CCN5 | c.144del p.D48Efs*55 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- GGCX | c.1295del p.T432Nfs*13 | Frame Shift Del (DEL) | VAF 48/196 reads (24%) | called by mutect2, pindel*, varscan2
- HTT | c.5120C>T p.S1707F | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2
- KHDRBS1 | c.729del p.M244Wfs*12 | Frame Shift Del (DEL) | VAF 27/109 reads (25%) | called by mutect2, pindel, varscan2
- B3GNT8 | c.510G>A p.T170= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs755856349, COSV99524592; called by muse, mutect2, varscan2
- CD93 | c.855C>T p.C285= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as rs777170426, COSV55662963, COSV99849248; called by muse, mutect2, varscan2
- CNGA3 | c.1842G>A p.E614= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1449266657, COSV55623169; called by muse, varscan2
- COL4A6 | c.2994A>G p.P998= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV100564173; called by muse, mutect2, varscan2
- DUOX1 | c.1011C>T p.G337= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs759548835, COSV100368013; called by muse, mutect2, varscan2
- FAM3A | c.132A>T p.P44= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100453646; called by muse, mutect2
- FCRL4 | c.798G>C p.V266= | Silent (SNP) | VAF 119/355 reads (34%) | catalogued as rs1223197534, COSV99619886; called by muse, mutect2, varscan2
- FZD4 | c.978T>C p.T326= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV101536049, COSV72294241; called by muse, mutect2, varscan2
- HIPK4 | c.855C>G p.L285= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99396704; called by muse, mutect2, varscan2
- HOXD3 | c.609C>T p.S203= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs373952633; called by muse, mutect2, varscan2
- IMPG2 | c.1929G>A p.E643= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs1481697671, COSV99515622; called by muse, mutect2, varscan2
- MAG | c.828C>T p.D276= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs755009472, COSV100727832; called by muse, mutect2, varscan2
- PAPPA | c.3216C>T p.I1072= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV60289009; called by muse, mutect2, varscan2
- PCDHA3 | c.102C>A p.S34= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs554911037, COSV100973645; called by muse, mutect2, varscan2
- PCSK2 | c.1029C>T p.Y343= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs1441737223, COSV52740544; called by muse, mutect2, varscan2
- PLEKHH1 | c.3565C>T p.L1189= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100233136; called by muse, varscan2
- PLPPR2 | c.105C>G p.R35= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99264497; called by muse, mutect2, varscan2
- SLC6A17 | c.6G>A p.P2= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs1348472691, COSV58996942; called by muse, mutect2, varscan2
- SOBP | c.516C>T p.S172= | Silent (SNP) | VAF 32/172 reads (19%) | catalogued as COSV100433167; called by muse, mutect2
- SYT12 | c.831G>A p.Q277= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs1301787953, COSV101210908; called by muse, mutect2, varscan2
- THEMIS2 | c.816C>G p.R272= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100198023; called by muse, varscan2
- TREX2 | c.189C>T p.L63= (on ENST00000334497; = p.L20= on NM_080701.3) | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100444149; called by muse, mutect2, varscan2
- RIMS2 | c.1692+133G>A | Intron (SNP) | VAF 23/150 reads (15%) | catalogued as COSV99169742; called by muse, mutect2, varscan2
- ZNF322P1 | n.139G>A | RNA (SNP) | VAF 16/396 reads (4%) | called by muse, mutect2
